CCDI case PBBUXI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/b154c27c-4ce4-4b15-ae61-330f973ff5b9

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Epithelial-myoepithelial carcinoma: ICD-O-3 morphology code: 8562/3; Tissue or organ of origin: Parotid gland; Age at diagnosis: 14.1 years (5,156 days).

Biospecimens (3 samples)
- Sample 0DI8M9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI8MC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI8ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
